Somatic mutation profile of tumor specimen MP2PRT-PASLCJ-TBP1-A (aliquot MP2PRT-PASLCJ-TBP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASLCJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.0 years (383 days).
Specimen MP2PRT-PASLCJ-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b051e97b-ea9b-467c-a160-d6967d0651b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASLCJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASLCJ-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/befbcd8b-a1dd-4b53-833a-b7435d4ca122

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2049A>C p.R683S | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519723, COSV67569539, COSV67577012; ClinVar: pathogenic; called by muse, mutect2, varscan2
- JAK2 | c.2624C>A p.T875N | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1057520016, COSV67598981; ClinVar: likely pathogenic; called by muse, mutect2
- BBS9 | c.1846C>T p.L616F (on ENST00000242067 / NM_001348036.1; = p.L576F on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as COSV54159662, COSV54175288; called by muse, mutect2
- CT55 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 104/438 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99358867; called by muse, mutect2, varscan2
- KIF21A | c.1775C>T p.S592L (on ENST00000361418 / NM_001378440.1; = p.S579L on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs147231078; called by muse, mutect2, varscan2
- RYR2 | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs955065308, CM097929, COSV63716501; ClinVar: uncertain significance; called by mutect2, varscan2
- UNC5C | c.870G>A p.P290= | Silent (SNP) | VAF 86/329 reads (26%) | catalogued as rs780532117, COSV71662187; called by muse, mutect2, varscan2
